Somatic mutation profile of tumor specimen C3N-01341-02 (aliquot CPT0095280009) from CPTAC case C3N-01341, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Age at diagnosis: 64.1 years (23,404 days).
Specimen C3N-01341-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9c269314-e41f-4134-a32e-a81cb9e64ac8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01341-31 (Blood Derived Normal), aliquot CPT0095300002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/265e4f74-588e-4931-9dff-5d346a1ad301

The open-access MAF lists 82 somatic variants for this specimen: 59 protein-altering or splice-affecting, 14 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 14, Nonsense Mutation 5, Frame Shift Del 4, In Frame Del 4, Splice Region 3, Intron 3, Splice Site 2, 5'UTR 2, RNA 1, 5'Flank 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1A | c.2077C>T p.R693* | Nonsense Mutation (SNP) | VAF 105/362 reads (29%) | hotspot (GDC flag); catalogued as COSV61375361; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 105/330 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ALDH16A1 | c.1805G>A p.R602Q | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs764398885; called by mutect2, varscan2
- ARFGEF2 | c.4790C>T p.T1597M | Missense Mutation (SNP) | VAF 136/491 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as rs368410119; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP13A1 | c.3124C>T p.R1042* | Nonsense Mutation (SNP) | VAF 58/179 reads (32%) | catalogued as COSV52283571; called by muse, mutect2, varscan2
- CACNG3 | c.220C>T p.R74* | Nonsense Mutation (SNP) | VAF 48/179 reads (27%) | catalogued as COSV50070934; called by muse, mutect2, varscan2
- CD109 | c.1645A>G p.I549V | Missense Mutation (SNP) | VAF 61/176 reads (35%) | SIFT tolerated (0.49); PolyPhen benign (0.05); catalogued as rs142958853; called by muse, mutect2, varscan2
- CDH4 | c.2665G>A p.G889R | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as rs1316308538, COSV64673299; called by muse, mutect2, varscan2
- CHRNA4 | c.147_149del p.N49del | In Frame Del (DEL) | VAF 100/387 reads (26%) | catalogued as rs780385531; called by pindel, varscan2
- CHST2 | c.1438G>A p.A480T | Missense Mutation (SNP) | VAF 69/202 reads (34%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.494); catalogued as rs755631191; called by muse, mutect2, varscan2
- COL4A4 | c.4831G>A p.G1611R | Missense Mutation (SNP) | VAF 93/300 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61636615; called by muse, mutect2, varscan2
- CTNS | c.926G>A p.G309D | Missense Mutation (SNP) | VAF 26/221 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM096644, CM123429; called by muse, mutect2, varscan2
- CUL4B | c.278C>T p.S93L | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.034); catalogued as rs747997744, COSV60686435; called by muse, mutect2, varscan2
- DACT2 | c.745G>A p.V249M | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as rs879304618; called by muse, mutect2, varscan2
- DLGAP2 | c.2450C>T p.A817V | Missense Mutation (SNP) | VAF 91/258 reads (35%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.994); catalogued as rs774180756, COSV70097614; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.227G>A p.R76Q | Missense Mutation (SNP) | VAF 57/203 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs776913738; called by muse, mutect2, varscan2
- ENPP6 | c.534G>A p.K178= | Splice Region (SNP) | VAF 23/68 reads (34%) | catalogued as rs1288558303, COSV99698752; called by muse, mutect2, varscan2
- FAT1 | c.844G>A p.D282N | Missense Mutation (SNP) | VAF 44/146 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs781077372, COSV71673661; called by muse, mutect2, varscan2
- FBN1 | c.8189G>A p.R2730Q | Missense Mutation (SNP) | VAF 141/479 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs200231626; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FIBP | c.607G>A p.A203T | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.968); catalogued as rs376153374; called by muse, mutect2, varscan2
- FOXL1 | c.104C>T p.A35V | Missense Mutation (SNP) | VAF 81/282 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV57214696, COSV57215334; called by muse, mutect2, varscan2
- LONP2 | c.394_396del p.E132del | In Frame Del (DEL) | VAF 30/111 reads (27%) | catalogued as rs1182709749; called by pindel, varscan2
- LRRC34 | c.1073T>C p.V358A (on ENST00000446859 / NM_001172779.2; = p.V326A on NM_153353.5) | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as rs543612719; called by muse, mutect2, varscan2
- MAP2K2 | c.984G>A p.E328= | Splice Region (SNP) | VAF 27/270 reads (10%) | catalogued as COSV53565239; called by muse, mutect2, varscan2
- MAP2K2 | c.211G>A p.D71N | Missense Mutation (SNP) | VAF 167/542 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV99501942; called by muse, mutect2, varscan2
- MAS1L | c.1007C>T p.A336V | Missense Mutation (SNP) | VAF 84/261 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.109); catalogued as rs566796111; called by muse, mutect2, varscan2
- NASP | c.557T>C p.M186T | Missense Mutation (SNP) | VAF 61/147 reads (41%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.104); catalogued as rs778834154; called by muse, mutect2, varscan2
- NKTR | c.3905C>T p.T1302M | Missense Mutation (SNP) | VAF 46/297 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.893); catalogued as rs773037322, COSV99236315; called by muse, mutect2, varscan2
- PTEN | c.143del p.N48Tfs*6 | Frame Shift Del (DEL) | VAF 73/253 reads (29%) | catalogued as COSV64298680; called by mutect2, pindel, varscan2
- RTTN | c.5651A>G p.N1884S | Missense Mutation (SNP) | VAF 54/182 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.053); catalogued as rs774834767, COSV55348217; called by muse, varscan2
- SETD5 | c.3115C>T p.R1039C | Missense Mutation (SNP) | VAF 69/195 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.348); catalogued as rs757367974, COSV56711181; called by muse, mutect2, varscan2
- SGK1 | c.1100_1102del p.K367del | In Frame Del (DEL) | VAF 36/104 reads (35%) | catalogued as rs1562235584; called by pindel, varscan2
- SMPD3 | c.733G>A p.V245M | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.395); catalogued as rs200081668, COSV54715870; called by muse, mutect2, varscan2
- SOGA1 | c.1786G>A p.V596M | Missense Mutation (SNP) | VAF 32/225 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761926055; called by muse, mutect2, varscan2
- SPOCK2 | c.708C>T p.S236= | Splice Region (SNP) | VAF 44/121 reads (36%) | catalogued as rs375998618; called by muse, mutect2, varscan2
- USP34 | c.5009G>A p.R1670H | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV68399155; called by muse, mutect2
- ZNF630 | c.1910G>T p.C637F | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs1556908195; called by muse, mutect2
- ARID1A | c.4231del p.Q1411Sfs*70 | Frame Shift Del (DEL) | VAF 36/127 reads (28%) | called by mutect2, pindel, varscan2
- ATR | c.2976+1G>A p.X992_splice | Splice Site (SNP) | VAF 55/186 reads (30%) | called by muse, mutect2, varscan2
- BCORL1 | c.4660G>T p.G1554C | Missense Mutation (SNP) | VAF 10/204 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.15); called by muse, mutect2
- BRD1 | c.1440G>A p.W480* | Nonsense Mutation (SNP) | VAF 27/104 reads (26%) | called by muse, mutect2, varscan2
- CADPS | c.787G>A p.A263T | Missense Mutation (SNP) | VAF 83/285 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- CRAT | c.1727_1743del p.V576Gfs*49 | Frame Shift Del (DEL) | VAF 54/316 reads (17%) | called by mutect2, pindel
- CTCF | c.1087-22_1087-2del p.X363_splice | Splice Site (DEL) | VAF 6/31 reads (19%) | called by mutect2, pindel
- EARS2 | c.545A>T p.D182V | Missense Mutation (SNP) | VAF 49/167 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- GLI2 | c.3752A>G p.Q1251R (on ENST00000361492 / NM_001374353.1; = p.Q1268R on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/150 reads (27%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- IGF2R | c.1982T>G p.I661R | Missense Mutation (SNP) | VAF 31/213 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- KMT2C | c.4745G>A p.G1582E | Missense Mutation (SNP) | VAF 72/238 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- OTOG | c.2636C>A p.A879D | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- PCDHB8 | c.1775C>T p.A592V | Missense Mutation (SNP) | VAF 54/532 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); called by mutect2, varscan2
- PINK1 | c.1610C>T p.A537V | Missense Mutation (SNP) | VAF 171/566 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- PNPLA6 | c.31G>T p.G11W | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- PTEN | c.740_742del p.L247_P248delinsS | In Frame Del (DEL) | VAF 75/329 reads (23%) | called by mutect2, pindel, varscan2
- PXDN | c.4130C>G p.S1377* | Nonsense Mutation (SNP) | VAF 20/194 reads (10%) | called by muse, mutect2, varscan2
- RIMS1 | c.4679C>A p.A1560E | Missense Mutation (SNP) | VAF 58/140 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RUNX3 | c.413_416del p.L138Pfs*14 | Frame Shift Del (DEL) | VAF 25/203 reads (12%) | called by mutect2, pindel, varscan2
- SCYL3 | c.201A>C p.R67S | Missense Mutation (SNP) | VAF 43/143 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SNED1 | c.661G>T p.D221Y | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- WDFY4 | c.3125C>A p.T1042K | Missense Mutation (SNP) | VAF 48/162 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- AC048338.2 | c.39G>A p.L13= | Silent (SNP) | VAF 68/205 reads (33%) | catalogued as rs1478619663; called by muse, mutect2, varscan2
- CLEC14A | c.354C>T p.S118= | Silent (SNP) | VAF 59/173 reads (34%) | called by muse, mutect2, varscan2
- CLPTM1L | c.633C>T p.P211= | Silent (SNP) | VAF 69/272 reads (25%) | catalogued as rs1208501122; called by muse, mutect2, varscan2
- COL16A1 | c.4416G>A p.P1472= | Silent (SNP) | VAF 34/136 reads (25%) | catalogued as rs775193676, COSV54700926; called by muse, mutect2, varscan2
- MAPK1 | c.1036C>T p.L346= | Silent (SNP) | VAF 24/179 reads (13%) | called by muse, mutect2, varscan2
- MROH2A | c.63C>T p.D21= | Silent (SNP) | VAF 49/183 reads (27%) | catalogued as rs538390853; called by muse, mutect2, varscan2
- MYH6 | c.2004T>C p.H668= | Silent (SNP) | VAF 201/581 reads (35%) | catalogued as rs1566511858; called by muse, mutect2, varscan2
- PES1 | c.780C>T p.A260= | Silent (SNP) | VAF 33/221 reads (15%) | catalogued as rs767389539; called by muse, mutect2, varscan2
- PPIB | c.261C>G p.G87= | Silent (SNP) | VAF 110/487 reads (23%) | called by muse, mutect2, varscan2
- PRR7 | c.759C>T p.P253= | Silent (SNP) | VAF 34/95 reads (36%) | catalogued as rs1466976366; called by muse, mutect2, varscan2
- SHOX | c.303C>T p.R101= | Silent (SNP) | VAF 104/417 reads (25%) | called by muse, mutect2, varscan2
- SIGIRR | c.1170C>T p.L390= | Silent (SNP) | VAF 32/86 reads (37%) | catalogued as rs762216833; called by muse, mutect2, varscan2
- ZFYVE26 | c.1704C>T p.D568= | Silent (SNP) | VAF 100/333 reads (30%) | catalogued as rs373958917; called by muse, mutect2, varscan2
- ZNF549 | c.255G>A p.A85= (on ENST00000376233 / NM_001199295.2; = p.A72= on NM_153263.2) | Silent (SNP) | VAF 38/124 reads (31%) | catalogued as rs746872707, COSV53724086; called by muse, mutect2
- ADAM12 | c.2113+845C>G | Intron (SNP) | VAF 64/241 reads (27%) | catalogued as COSV64109135; called by muse, mutect2, varscan2
- ADGRV1 | c.-74A>C | 5'UTR (SNP) | VAF 75/279 reads (27%) | called by muse, mutect2, varscan2
- AL109984.1 | n.186+1350C>A | Intron (SNP) | VAF 45/161 reads (28%) | called by muse, mutect2, varscan2
- BHLHE22 | chr8:64576433 C>A | 5'Flank (SNP) | VAF 47/182 reads (26%) | called by muse, mutect2, varscan2
- BNIP3L | c.-46C>A | 5'UTR (SNP) | VAF 82/280 reads (29%) | called by muse, mutect2, varscan2
- CCAR1 | c.-51+309C>T | Intron (SNP) | VAF 10/101 reads (10%) | catalogued as rs950031217; called by muse, mutect2, varscan2
- FHL1 | c.*972A>T | 3'UTR (SNP) | VAF 29/205 reads (14%) | called by muse, mutect2, varscan2
- MYADM | chr19:53874365 G>T | 3'Flank (SNP) | VAF 44/143 reads (31%) | called by muse, mutect2, varscan2
- OR2W5 | n.640G>A | RNA (SNP) | VAF 113/349 reads (32%) | catalogued as rs539598708; called by muse, mutect2, varscan2
